Somatic mutation profile of tumor specimen BA2494D (aliquot aq-BA2494D) from BEATAML1.0 case 2246, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.7 years (22,163 days).
Specimen BA2494D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c581d0ff-b0ca-4972-a1a0-7bea8c6d5acc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2849D (Solid Tissue Normal), aliquot aq-BA2849D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40e250c7-377e-44f7-beb3-5710b87f110c

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 5, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4533G>A p.M1511I | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53981484; called by muse, varscan2
- GUCY1A1 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs749771282, COSV56650537; called by muse, mutect2, varscan2
- RUNX1 | c.930dup p.A311Rfs*262 (on ENST00000344691 / NM_001001890.3; = p.A338Rfs*262 on NM_001754.5) | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | catalogued as rs1439534438; called by mutect2, pindel, varscan2
- TET2 | c.3782G>T p.R1261L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54395386, COSV54396706, COSV99485827; called by muse, mutect2, varscan2
- ANKRD63 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- DISP2 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- EZH2 | c.892+1G>A p.X298_splice (on ENST00000460911 / NM_001203247.2; = p.R298H on NM_004456.5) | Splice Site (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- FOXO4 | c.1467C>A p.D489E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2
- MACF1 | c.7887C>A p.C2629* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- SMAD1 | c.1255-2A>G p.X419_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- AMBP | c.474G>A p.R158= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV54323639; called by muse, mutect2
- ATP8B3 | c.3687C>T p.S1229= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs373632059; called by muse, mutect2, varscan2
- BTBD8 | c.4824C>T p.S1608= (on ENST00000636805 / NM_001376131.1; = p.S1095= on NM_015237.4) | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV64883879; called by muse, varscan2
- DGKK | c.1815G>T p.V605= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- WDR74 | c.57C>A p.I19= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs751927322; called by muse, mutect2, varscan2
